Somatic mutation profile of tumor specimen C3N-03875-01 (aliquot CPT0237410007) from CPTAC case C3N-03875, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 68.1 years (24,881 days).
Specimen C3N-03875-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cee681df-60d2-4818-b0f1-91852b2ba524.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03875-31 (Blood Derived Normal), aliquot CPT0237470002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d88eb607-3685-4282-a03e-fdfff7667866

The open-access MAF lists 707 somatic variants for this specimen: 467 protein-altering or splice-affecting, 142 silent, 98 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 399, Silent 142, Intron 49, Nonsense Mutation 31, Frame Shift Del 20, RNA 19, 5'UTR 12, 3'UTR 11, Splice Site 7, Splice Region 7, 3'Flank 4, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NALCN | c.1733A>G p.Y578C | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs786203988, CM151802; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PROP1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 79/414 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs137853100, CM030084; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.733G>C p.G245R | Missense Mutation (SNP) | VAF 97/319 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.3545A>G p.Y1182C | Missense Mutation (SNP) | VAF 83/157 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1362624575; called by muse, mutect2, varscan2
- ADAMTS13 | c.2581G>A p.G861R | Missense Mutation (SNP) | VAF 22/431 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1371570379, COSV63022254; called by muse, mutect2
- ADCY1 | c.831G>T p.M277I | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV52036231; called by muse, mutect2, varscan2
- ADGRG1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 141/1050 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs767100119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AK8 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779744213; called by muse, mutect2, varscan2
- AMER3 | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs777954595, COSV58470440; called by muse, mutect2, varscan2
- ANKRD9 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 220/409 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs1304126703; called by muse, mutect2, varscan2
- APLP1 | c.1894C>A p.R632S (on ENST00000221891 / NM_001024807.3; = p.R631S on NM_005166.4) | Missense Mutation (SNP) | VAF 107/350 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.22); catalogued as COSV55703975; called by mutect2, varscan2
- ARHGEF11 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 91/191 reads (48%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs867791189; called by muse, mutect2, varscan2
- ASH1L | c.581C>G p.S194C | Missense Mutation (SNP) | VAF 46/275 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.322); catalogued as rs992836176; called by muse, mutect2, varscan2
- ATG13 | c.594C>T p.T198= | Splice Region (SNP) | VAF 65/307 reads (21%) | catalogued as rs1243629998; called by muse, mutect2, varscan2
- BRSK2 | c.868C>G p.R290G | Missense Mutation (SNP) | VAF 123/411 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV57542926; called by muse, mutect2, varscan2
- C1QTNF2 | c.196G>A p.A66T (on ENST00000393975; = p.A21T on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.093); catalogued as rs374426172; called by muse, mutect2, varscan2
- C1orf94 | c.1543C>G p.Q515E (on ENST00000488417 / NM_001134734.2; = p.Q325E on NM_032884.5) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV64913312; called by muse, mutect2, varscan2
- CAMTA1 | c.4066C>T p.R1356W | Missense Mutation (SNP) | VAF 59/341 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as rs777480195, COSV57916271; called by muse, mutect2, varscan2
- CBL | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.745); catalogued as COSV50634532; called by muse, mutect2, varscan2
- CCNY | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374349988; called by muse, mutect2, varscan2
- CCT2 | c.1570G>T p.A524S | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV54740989; called by muse, mutect2, varscan2
- CDK14 | c.802G>A p.G268R (on ENST00000380050 / NM_001287135.2; = p.G250R on NM_012395.3) | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV56038854; called by muse, mutect2, varscan2
- CHRNB3 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 105/397 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1456799585; called by muse, mutect2, varscan2
- CHST12 | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 78/436 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99324458; called by muse, mutect2, varscan2
- CILP | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 86/228 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.934); catalogued as rs781026100; called by muse, mutect2, varscan2
- CLK1 | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs56049927; called by muse, mutect2, varscan2
- CLNK | c.663G>T p.Q221H | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1291253207; called by muse, mutect2, varscan2
- CNR1 | c.748C>A p.L250M | Missense Mutation (SNP) | VAF 119/286 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62991000; called by muse, mutect2, varscan2
- COL5A2 | c.4484C>T p.P1495L | Missense Mutation (SNP) | VAF 80/443 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as rs1173449762; called by muse, mutect2, varscan2
- CSF3R | c.312C>A p.N104K | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs750132507; called by muse, mutect2, varscan2
- CSPP1 | c.2884C>A p.R962S (on ENST00000676605; = p.R921S on NM_024790.6) | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51580264; called by muse, mutect2, varscan2
- DAW1 | c.794G>C p.S265T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV59364858; called by muse, mutect2, varscan2
- DMBT1 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 238/571 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as COSV100353491; called by muse, mutect2, varscan2
- DNAH17 | c.2399C>A p.S800* | Nonsense Mutation (SNP) | VAF 231/357 reads (65%) | catalogued as rs141150806; called by muse, mutect2, varscan2
- DRD3 | c.135C>A p.F45L | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55679040; called by muse, mutect2, varscan2
- DVL3 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 144/281 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.578); catalogued as rs1445429055; called by muse, mutect2, varscan2
- EMC2 | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1420349258; called by muse, mutect2, varscan2
- EPX | c.2108G>A p.R703H | Missense Mutation (SNP) | VAF 161/318 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as rs538257523; called by mutect2, varscan2
- EVC | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 163/384 reads (42%) | catalogued as rs373502728; called by mutect2, varscan2
- FAM120B | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 246/513 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.132); catalogued as rs1408417799; called by muse, mutect2, varscan2
- FAM135B | c.2428G>T p.G810* | Nonsense Mutation (SNP) | VAF 57/286 reads (20%) | catalogued as COSV52703658; called by muse, mutect2, varscan2
- FAM135B | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 22/161 reads (14%) | catalogued as COSV52744513; called by muse, mutect2, varscan2
- FAM171A1 | c.2305G>C p.V769L | Missense Mutation (SNP) | VAF 110/228 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV65315873; called by muse, mutect2, varscan2
- FRMPD3 | c.2602C>T p.R868C | Missense Mutation (SNP) | VAF 32/365 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs752030207, COSV52188319; called by muse, mutect2
- GALNT17 | c.1273G>T p.G425* | Nonsense Mutation (SNP) | VAF 26/161 reads (16%) | catalogued as COSV100351621, COSV61162908; called by muse, mutect2
- GAPDHS | c.445C>A p.Q149K | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as COSV99722682; called by muse, mutect2, varscan2
- GNB4 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 14/329 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51711335; called by muse, mutect2
- GPR141 | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.471); catalogued as rs369757172, COSV57732683; called by muse, mutect2, varscan2
- GPR174 | c.557T>C p.M186T | Missense Mutation (SNP) | VAF 103/191 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1370997998; called by muse, mutect2, varscan2
- GPR20 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 111/289 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.056); catalogued as COSV66685176; called by muse, mutect2, varscan2
- GRK2 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 119/381 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57952703; called by muse, mutect2, varscan2
- GUCY1A2 | c.1864G>T p.V622L | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56477596; called by muse, mutect2, varscan2
- HGF | c.1361C>A p.T454K | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55945201, COSV55953678; called by muse, mutect2, varscan2
- HYDIN | c.7574G>T p.R2525L | Missense Mutation (SNP) | VAF 100/397 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs756437118, COSV59262649; called by muse, mutect2, varscan2
- IGF2R | c.2867A>G p.Y956C | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1326579794; called by muse, mutect2, varscan2
- IGSF3 | c.1159G>C p.G387R | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59590016; called by muse, mutect2, varscan2
- IL36B | c.435G>T p.R145S | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV52086896, COSV52088255; called by muse, mutect2, varscan2
- KCNH5 | c.2673G>T p.Q891H | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.336); catalogued as COSV59760724; called by muse, varscan2
- KHSRP | c.851G>T p.R284L | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67919777; called by muse, mutect2, varscan2
- KLHL36 | c.1529G>T p.R510L | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.591); catalogued as COSV50721078; called by muse, mutect2, varscan2
- KMT2D | c.5867G>T p.R1956M | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as CX114927; called by muse, mutect2, varscan2
- KRTAP20-2 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 84/366 reads (23%) | PolyPhen possibly damaging (0.877); catalogued as COSV58183384, COSV58183700; called by muse, mutect2, varscan2
- LONP2 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs771290405, COSV53522648; called by muse, mutect2, varscan2
- MAGEB3 | c.764T>A p.L255H | Missense Mutation (SNP) | VAF 122/213 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV64397478; called by muse, mutect2, varscan2
- MCPH1 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100765221; called by muse, mutect2, varscan2
- MGAM2 | c.4421G>A p.G1474E | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs561493278; called by muse, mutect2, varscan2
- MOCS1 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 97/238 reads (41%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.603); catalogued as rs200517455, COSV57934931; called by muse, mutect2, varscan2
- MS4A2 | c.669C>G p.N223K | Missense Mutation (SNP) | VAF 62/337 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as COSV99627186; called by muse, mutect2, varscan2
- MUC16 | c.32708C>A p.P10903Q | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.012); catalogued as rs780761357; called by muse, mutect2, varscan2
- MYH9 | c.2114G>T p.R705L | Missense Mutation (SNP) | VAF 159/473 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM002810; called by muse, mutect2, varscan2
- NBEA | c.1912G>A p.G638R | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59819274; called by muse, mutect2, varscan2
- NEGR1 | c.554del p.G185Dfs*30 | Frame Shift Del (DEL) | VAF 25/154 reads (16%) | catalogued as COSV60841478; called by mutect2, pindel, varscan2
- NINL | c.2816G>C p.R939P | Missense Mutation (SNP) | VAF 166/600 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs766474048; called by muse, mutect2, varscan2
- NINL | c.2375G>A p.S792N | Missense Mutation (SNP) | VAF 100/505 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs760120921; called by muse, mutect2, varscan2
- NLRP5 | c.1264G>T p.V422L | Missense Mutation (SNP) | VAF 100/308 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as COSV66761889; called by muse, mutect2, varscan2
- NOVA2 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 56/384 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV54359382; called by muse, mutect2, varscan2
- NPAP1 | c.242C>A p.P81H | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV61509617; called by muse, mutect2, varscan2
- NRK | c.3680G>T p.R1227L | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV54597607; called by muse, mutect2, varscan2
- OLFML3 | c.415A>G p.I139V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs138164881; called by muse, mutect2
- OR2H1 | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 114/298 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV65810186; called by muse, mutect2, varscan2
- OR5A1 | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57376952; called by muse, mutect2, varscan2
- OR5I1 | c.341C>A p.S114Y | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV56887263; called by muse, mutect2, varscan2
- OR6C3 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.089); catalogued as COSV65570792; called by mutect2, varscan2
- OR9Q2 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 76/474 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV61112386; called by muse, mutect2, varscan2
- OSER1 | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs779641135, COSV54854790; called by muse, mutect2, varscan2
- P2RY8 | c.170C>G p.P57R | Missense Mutation (SNP) | VAF 161/387 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as COSV67177677; called by muse, mutect2, varscan2
- P4HTM | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 125/290 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs756516236; called by muse, mutect2, varscan2
- PAK5 | c.1485C>T p.V495= | Splice Region (SNP) | VAF 25/166 reads (15%) | catalogued as rs768615574, COSV62021572; called by muse, varscan2
- PAPPA2 | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 143/277 reads (52%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs1310852318, COSV62787113; called by muse, mutect2, varscan2
- PAX1 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 149/499 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV101270238; called by muse, mutect2, varscan2
- PCLO | c.533T>G p.L178W | Missense Mutation (SNP) | VAF 58/347 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV61637214; called by muse, mutect2, varscan2
- PCNX1 | c.866C>G p.S289C | Missense Mutation (SNP) | VAF 48/505 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV53096716; called by muse, mutect2
- PCOLCE | c.553A>T p.S185C | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV53824657; called by muse, mutect2, varscan2
- PDE1A | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59519899; called by muse, mutect2, varscan2
- PDZK1IP1 | c.192G>T p.M64I | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV53744555; called by muse, mutect2, varscan2
- PHOX2A | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 110/315 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99996285; called by muse, mutect2, varscan2
- PIWIL2 | c.1582C>T p.H528Y | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs374959539; called by muse, mutect2, varscan2
- PKD1L1 | c.3811G>T p.G1271C | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99220757; called by muse, mutect2, varscan2
- PLCB4 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758219894, COSV53798157, COSV99596637; called by muse, mutect2, varscan2
- PLOD1 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 110/468 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs763065699, COSV52144518; ClinVar: uncertain significance; called by muse, varscan2
- PODN | c.1226T>C p.L409S (on ENST00000395871; = p.L361S on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/526 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57013037; called by muse, mutect2, varscan2
- POLR1A | c.2528G>T p.R843L | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.138); catalogued as rs762778123, COSV55689100, COSV99808547; called by muse, mutect2, varscan2
- POTEE | c.2650G>T p.E884* | Nonsense Mutation (SNP) | VAF 273/1300 reads (21%) | catalogued as rs779229923, COSV100388436, COSV58224609; called by muse, varscan2
- PRDM16 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs760432567; called by muse, mutect2, varscan2
- PREX1 | c.4547C>A p.S1516Y | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1406987493; called by muse, mutect2, varscan2
- PREX1 | c.4515C>A p.Y1505* | Nonsense Mutation (SNP) | VAF 82/391 reads (21%) | catalogued as COSV64253052; called by muse, mutect2
- PRKCB | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.296); catalogued as COSV57799543; called by muse, mutect2, varscan2
- PRKCG | c.944T>A p.V315E | Missense Mutation (SNP) | VAF 68/410 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV54734540; called by muse, mutect2, varscan2
- PRR23A | c.396G>T p.R132S | Missense Mutation (SNP) | VAF 123/447 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.149); catalogued as rs762548197; called by muse, mutect2, varscan2
- RAB11FIP2 | c.188A>G p.E63G | Missense Mutation (SNP) | VAF 131/279 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100843065; called by muse, mutect2, varscan2
- RAPGEF1 | c.1193C>G p.S398C | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64703225; called by muse, mutect2, varscan2
- RFLNB | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs573028386; called by muse, mutect2
- RFX8 | c.1419G>T p.R473S (on ENST00000646446; = p.R402S on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV65178276, COSV65178986; called by muse, mutect2, varscan2
- RGS7 | c.1436del p.P479Hfs*10 (on ENST00000440928 / NM_001374810.1; = p.P408Hfs*10 on NM_001282773.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 48/124 reads (39%) | catalogued as rs1558270873; called by mutect2, pindel, varscan2
- RTL1 | c.2683G>T p.D895Y | Missense Mutation (SNP) | VAF 48/281 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV66017312; called by muse, mutect2, varscan2
- RYR1 | c.2119G>A p.G707S | Missense Mutation (SNP) | VAF 45/275 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376526576, CM137492; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL4 | c.2254G>A p.G752S | Missense Mutation (SNP) | VAF 61/444 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as rs535960309; called by muse, mutect2, varscan2
- SCN3A | c.3661G>T p.G1221C | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769359817; called by muse, mutect2, varscan2
- SEMA4C | c.1975del p.L659Wfs*87 | Frame Shift Del (DEL) | VAF 41/322 reads (13%) | catalogued as rs1436989321; called by pindel, varscan2
- SHBG | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 173/441 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV52646235; called by muse, mutect2, varscan2
- SHROOM3 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 152/478 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56040270; called by muse, mutect2, varscan2
- SIPA1L3 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs375334517; called by muse, mutect2, varscan2
- SLC26A7 | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 27/178 reads (15%) | catalogued as rs866779922; called by muse, mutect2, varscan2
- SLC5A2 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 286/865 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.778); catalogued as rs746746841, COSV57891632; called by muse, mutect2, varscan2
- SLC7A13 | c.1180-1G>T p.X394_splice | Splice Site (SNP) | VAF 28/87 reads (32%) | catalogued as rs1320016986, COSV99879198; called by muse, mutect2, varscan2
- SLC8A1 | c.1419G>T p.K473N | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100246306, COSV60478909; called by muse, mutect2, varscan2
- SMARCC2 | c.2767C>T p.Q923* | Nonsense Mutation (SNP) | VAF 79/466 reads (17%) | catalogued as rs1373379578, COSV99519580; called by muse, mutect2, varscan2
- SPAG6 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as rs994812122; called by muse, mutect2, varscan2
- SPATA4 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 65/310 reads (21%) | catalogued as rs772818436; called by muse, mutect2, varscan2
- SYNM | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 225/607 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); catalogued as rs782178027; called by muse, mutect2, varscan2
- SYT4 | c.1179G>T p.L393F | Missense Mutation (SNP) | VAF 201/426 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.132); catalogued as rs1312649033; called by muse, mutect2, varscan2
- TBC1D23 | c.1679A>G p.Y560C (on ENST00000394144 / NM_001199198.3; = p.Y545C on NM_018309.5) | Missense Mutation (SNP) | VAF 72/221 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs1294288393; called by muse, mutect2, varscan2
- TECTA | c.3137C>T p.A1046V | Missense Mutation (SNP) | VAF 94/475 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV50698862; called by muse, mutect2, varscan2
- TEKT1 | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as COSV58625116; called by muse, mutect2, varscan2
- TF | c.1595del p.G532Dfs*21 | Frame Shift Del (DEL) | VAF 98/365 reads (27%) | catalogued as COSV53919873; called by mutect2, pindel, varscan2
- THBS2 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100827847; called by muse, mutect2, varscan2
- TMEFF1 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477149491; called by muse, mutect2, varscan2
- TMEM51 | c.462G>C p.L154F | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.074); catalogued as rs1003983296; called by muse, mutect2, varscan2
- TNIP3 | c.53C>A p.T18K | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as rs144762502; called by muse, mutect2, varscan2
- TPO | c.2789C>T p.P930L | Missense Mutation (SNP) | VAF 118/341 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs924720161; called by muse, mutect2, varscan2
- TRIM56 | c.1606C>G p.L536V | Missense Mutation (SNP) | VAF 134/287 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV100047003; called by muse, mutect2, varscan2
- TSPAN8 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs754482138; called by muse, mutect2
- TTN | c.2513del p.A838Vfs*22 (on ENST00000591111; = p.A792Vfs*22 on NM_003319.4) | Frame Shift Del (DEL) | VAF 79/292 reads (27%) | catalogued as COSV59997050; called by mutect2, pindel, varscan2
- TTPA | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 84/287 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762517172; called by muse, mutect2, varscan2
- ULBP3 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.034); catalogued as rs752756870, COSV66254466; called by mutect2, varscan2
- USP17L7 | c.1234C>T p.H412Y | Missense Mutation (SNP) | VAF 307/813 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.904); catalogued as rs547069010; called by muse, mutect2, varscan2
- VSIG10 | c.1067A>T p.Q356L | Missense Mutation (SNP) | VAF 84/200 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV63652230; called by muse, mutect2, varscan2
- ZNF429 | c.510G>T p.K170N | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as COSV100641942; called by muse, mutect2, varscan2
- ZNF641 | c.457A>G p.I153V | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.361); catalogued as rs1425770809; called by muse, mutect2, varscan2
- ZNF688 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV56299917, COSV56300306, COSV99794398; called by muse, mutect2, varscan2
- ZNF804A | c.902G>A p.S301N | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56472830; called by muse, mutect2, varscan2
- ZNF804A | c.2531C>A p.P844H | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV56469075; called by muse, mutect2, varscan2
- ZNF831 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 133/420 reads (32%) | catalogued as COSV64041066; called by muse, mutect2, varscan2
- A2ML1 | c.845T>A p.L282H | Missense Mutation (SNP) | VAF 96/197 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ABCB4 | c.3058T>A p.Y1020N | Missense Mutation (SNP) | VAF 185/517 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ACAN | c.5129C>A p.P1710H | Missense Mutation (SNP) | VAF 117/277 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ACBD5 | c.1276G>T p.V426L (on ENST00000375888 / NM_001352568.1; = p.V417L on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/241 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADD2 | c.655A>T p.R219W | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFF3 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- AGXT | c.216C>A p.N72K | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGXT2 | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 203/512 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AHNAK | c.17092G>T p.G5698C | Missense Mutation (SNP) | VAF 62/286 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKAR | c.362G>C p.S121T | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ANKRD44 | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 48/315 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ANTXR1 | c.1694A>G p.*565Wext*23 | Nonstop Mutation (SNP) | VAF 50/155 reads (32%) | called by muse, mutect2, varscan2
- ANTXRL | c.1704G>T p.Q568H | Missense Mutation (SNP) | VAF 147/368 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- AP2A1 | c.2200G>T p.G734C | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- ARHGEF26 | c.1663G>T p.E555* | Nonsense Mutation (SNP) | VAF 50/142 reads (35%) | called by muse, mutect2, varscan2
- ARID1A | c.4443G>T p.M1481I | Missense Mutation (SNP) | VAF 85/380 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ASPM | c.9857G>C p.C3286S | Missense Mutation (SNP) | VAF 135/341 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATN1 | c.26C>G p.S9W | Missense Mutation (SNP) | VAF 170/393 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AUTS2 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C10orf71 | c.2876C>A p.P959Q | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- C12orf4 | c.362G>A p.W121* | Nonsense Mutation (SNP) | VAF 84/463 reads (18%) | called by muse, mutect2, varscan2
- C1QTNF1 | c.624C>G p.Y208* | Nonsense Mutation (SNP) | VAF 160/271 reads (59%) | called by muse, mutect2, varscan2
- C4orf17 | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CAB39L | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- CACNA1A | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CACNB1 | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 106/317 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CACNG7 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 55/383 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- CAPN15 | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 91/389 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CARS1 | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASP14 | c.519G>T p.E173D | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CBLC | c.769A>T p.K257* | Nonsense Mutation (SNP) | VAF 37/205 reads (18%) | called by muse, mutect2, varscan2
- CCDC141 | c.3427G>T p.E1143* | Nonsense Mutation (SNP) | VAF 67/218 reads (31%) | called by muse, mutect2, varscan2
- CCDC168 | c.15895G>T p.G5299C | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC168 | c.3158T>A p.V1053D | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CCDC170 | c.1269C>G p.D423E | Missense Mutation (SNP) | VAF 113/233 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CCDC173 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC74B | c.862C>A p.L288M | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCT6B | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CD1E | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDK19 | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CDKN2A | c.293_305del p.H98Rfs*44 | Frame Shift Del (DEL) | VAF 286/832 reads (34%) | called by mutect2, pindel, varscan2
- CENPU | c.320+1G>T p.X107_splice | Splice Site (SNP) | VAF 41/88 reads (47%) | called by muse, mutect2, varscan2
- CHD6 | c.4745G>T p.R1582L | Missense Mutation (SNP) | VAF 84/307 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- CHD6 | c.3286G>T p.E1096* | Nonsense Mutation (SNP) | VAF 95/295 reads (32%) | called by muse, mutect2, varscan2
- CLC | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 49/386 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- CLIP4 | c.573G>T p.L191F | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLPSL2 | c.84+7C>A | Splice Region (SNP) | VAF 61/132 reads (46%) | called by muse, mutect2, varscan2
- CNGA1 | c.1641C>A p.N547K | Missense Mutation (SNP) | VAF 54/318 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- CNR1 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 109/228 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- COL11A1 | c.2167G>T p.A723S | Missense Mutation (SNP) | VAF 46/296 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL22A1 | c.4858C>A p.P1620T | Missense Mutation (SNP) | VAF 125/358 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- COL2A1 | c.1673G>T p.G558V | Missense Mutation (SNP) | VAF 111/679 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A2 | c.4024C>A p.L1342I | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- COL6A5 | c.4353G>T p.K1451N | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COMMD1 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- COPS7A | c.752A>T p.Q251L | Missense Mutation (SNP) | VAF 213/448 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPB1 | c.1046del p.G349Afs*71 | Frame Shift Del (DEL) | VAF 60/322 reads (19%) | called by mutect2, pindel, varscan2
- CPE | c.613G>C p.G205R | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CSMD2 | c.2364C>G p.Y788* | Nonsense Mutation (SNP) | VAF 26/166 reads (16%) | called by muse, mutect2, varscan2
- CSMD3 | c.6834G>C p.R2278S (on ENST00000297405 / NM_001363185.1; = p.R2174S on NM_052900.3) | Missense Mutation (SNP) | VAF 66/292 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- CST7 | c.182dup p.N61Kfs*49 | Frame Shift Ins (INS) | VAF 47/288 reads (16%) | called by mutect2, pindel, varscan2
- CTPS2 | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- CTPS2 | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); called by muse, varscan2
- CZIB | c.81G>T p.W27C | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DCAF8L1 | c.1115A>T p.N372I | Missense Mutation (SNP) | VAF 80/131 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DDX39B | c.736-3C>T | Splice Region (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- DHX34 | c.531G>T p.E177D | Missense Mutation (SNP) | VAF 107/314 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DKK4 | c.8_9delinsA p.A3Efs*7 | Frame Shift Del (DEL) | VAF 62/365 reads (17%) | called by pindel, varscan2*
- DLG5 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- DMBT1 | c.922T>A p.S308T | Missense Mutation (SNP) | VAF 237/562 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- DNAH11 | c.6755G>A p.G2252E | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- DNAH3 | c.571G>T p.V191L | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJB7 | c.185_186delinsA p.R62Qfs*12 | Frame Shift Del (DEL) | VAF 38/131 reads (29%) | called by pindel, varscan2*
- DOCK3 | c.2317C>G p.L773V | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- DOK5 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- DPP4 | c.2267G>C p.S756T | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.013); called by muse, mutect2
- DPYSL3 | c.1562del p.G521Afs*10 | Frame Shift Del (DEL) | VAF 46/307 reads (15%) | called by mutect2, pindel, varscan2
- DSCAML1 | c.719del p.G240Afs*39 (on ENST00000321322; = p.G180Afs*39 on NM_020693.4) | Frame Shift Del (DEL) | VAF 28/160 reads (18%) | called by mutect2, pindel, varscan2
- EEF1AKMT4-ECE2 | c.983C>G p.P328R | Missense Mutation (SNP) | VAF 89/456 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- EMILIN2 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 107/420 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- EMX1 | c.312del p.A105Rfs*19 | Frame Shift Del (DEL) | VAF 103/327 reads (31%) | called by mutect2, pindel, varscan2
- EP400 | c.5724C>G p.I1908M | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ERBB3 | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 203/674 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ERI3 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERICH3 | c.1355T>C p.V452A | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ETS1 | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- F13B | c.998A>T p.K333M | Missense Mutation (SNP) | VAF 211/458 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FAM9A | c.266C>A p.T89K | Missense Mutation (SNP) | VAF 79/153 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- FCER2 | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- FCN1 | c.669C>A p.F223L | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- FOXK2 | c.168_169del p.I56Mfs*113 | Frame Shift Del (DEL) | VAF 252/591 reads (43%) | called by mutect2, pindel, varscan2
- FOXL1 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 302/935 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- FOXN3 | c.688G>T p.G230C | Missense Mutation (SNP) | VAF 152/344 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.535); called by mutect2, varscan2
- FSCB | c.1172del p.K391Rfs*22 | Frame Shift Del (DEL) | VAF 30/298 reads (10%) | called by mutect2, pindel, varscan2
- FXYD2 | c.36del p.K13Rfs*19 | Frame Shift Del (DEL) | VAF 56/350 reads (16%) | called by mutect2, pindel, varscan2
- GABRA4 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- GALNT18 | c.1417-1G>T p.X473_splice | Splice Site (SNP) | VAF 50/144 reads (35%) | called by muse, mutect2, varscan2
- GCNT1 | c.178A>T p.T60S | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLYATL2 | c.563G>A p.S188N | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GLYATL2 | c.562A>T p.S188C | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GNL2 | c.964G>T p.G322C | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOLT1A | c.25+2T>C p.X9_splice | Splice Site (SNP) | VAF 46/135 reads (34%) | called by muse, mutect2, varscan2
- GPAM | c.2093G>T p.G698V | Missense Mutation (SNP) | VAF 140/320 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- GPR12 | c.983C>A p.A328E | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- GPR17 | c.431A>T p.Y144F | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR6 | c.122C>A p.A41E | Missense Mutation (SNP) | VAF 219/454 reads (48%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GPR61 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- GRAMD1B | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIN2B | c.194T>C p.V65A | Missense Mutation (SNP) | VAF 256/715 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRK5 | c.1210A>G p.T404A | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GTF3C5 | c.7G>C p.A3P | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- HDGFL2 | c.471G>T p.R157S | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- HDLBP | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 98/464 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- HEPH | c.3171G>T p.E1057D (on ENST00000343002; = p.E790D on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/155 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- HEPHL1 | c.2255G>T p.W752L | Missense Mutation (SNP) | VAF 53/276 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- HERC2 | c.7503G>T p.W2501C | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- HGH1 | c.256G>C p.V86L | Missense Mutation (SNP) | VAF 153/418 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- HKDC1 | c.2492A>C p.Q831P | Missense Mutation (SNP) | VAF 112/240 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HMCN2 | c.5518C>A p.P1840T | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IFT80 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 37/179 reads (21%) | called by muse, mutect2, varscan2
- IGKV3D-7 | c.150G>C p.Q50H | Missense Mutation (SNP) | VAF 59/640 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, varscan2
- IGSF3 | c.2566G>A p.V856I (on ENST00000369486 / NM_001007237.3; = p.V876I on NM_001542.4) | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- INSM2 | c.1633A>T p.N545Y | Missense Mutation (SNP) | VAF 110/291 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- INTS1 | c.1786G>C p.V596L | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- IRAG1 | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 114/458 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGA8 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGB2 | c.1308G>T p.Q436H (on ENST00000302347; = p.Q412H on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/410 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITGB8 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITIH2 | c.2200C>G p.P734A | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- KALRN | c.7423G>C p.V2475L (on ENST00000360013 / NM_001024660.4; = p.V778L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KBTBD3 | c.1392G>T p.E464D | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA6 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 84/152 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- KCND3 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 122/452 reads (27%) | called by muse, mutect2, varscan2
- KCNJ1 | c.520A>C p.M174L | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KDM6A | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF4B | c.1927A>G p.M643V | Missense Mutation (SNP) | VAF 181/571 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- KYAT3 | c.1250A>T p.N417I | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- LAMA3 | c.3815G>T p.G1272V | Missense Mutation (SNP) | VAF 165/587 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA5 | c.7410G>T p.Q2470H | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- LCOR | c.4633G>T p.D1545Y | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- LCT | c.3798C>A p.D1266E | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- LILRB1 | c.1634-5C>A | Splice Region (SNP) | VAF 45/113 reads (40%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.293G>C p.G98A | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAP2K2 | c.919+1G>T p.X307_splice | Splice Site (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- MAX | c.471G>C p.M157I | Missense Mutation (SNP) | VAF 156/649 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MBD5 | c.2299A>T p.N767Y | Missense Mutation (SNP) | VAF 59/302 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- MED24 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 102/222 reads (46%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- METTL15 | c.718G>T p.V240F | Missense Mutation (SNP) | VAF 39/289 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- MICAL3 | c.2189T>A p.L730Q | Missense Mutation (SNP) | VAF 113/261 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- MMP23B | c.963C>A p.C321* | Nonsense Mutation (SNP) | VAF 52/322 reads (16%) | called by muse, mutect2, varscan2
- MMRN1 | c.3343_3344delinsT p.G1115Ffs*48 | Frame Shift Del (DEL) | VAF 48/166 reads (29%) | called by pindel, varscan2*
- MMRN2 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 116/311 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- MRGPRG | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- MROH2A | c.1401G>A p.W467* | Nonsense Mutation (SNP) | VAF 56/304 reads (18%) | called by muse, mutect2, varscan2
- MS4A12 | c.401G>T p.W134L | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MTF2 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTOR | c.952A>T p.S318C | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- MUC16 | c.35303C>A p.P11768Q | Missense Mutation (SNP) | VAF 17/328 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.542); called by muse, mutect2
- MUC17 | c.3307C>A p.L1103I | Missense Mutation (SNP) | VAF 55/371 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MUC19 | c.850A>T p.S284C | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- MXD3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 236/475 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH1 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 26/449 reads (6%) | called by muse, mutect2
- MYH11 | c.2250G>A p.M750I | Missense Mutation (SNP) | VAF 302/1004 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO7A | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYOM2 | c.2507C>A p.P836H | Missense Mutation (SNP) | VAF 100/449 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAALAD2 | c.1735G>T p.D579Y | Missense Mutation (SNP) | VAF 51/315 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NEB | c.2335G>T p.G779C | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2
- NEFH | c.2681A>T p.K894M | Missense Mutation (SNP) | VAF 209/633 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- NETO1 | c.469+1G>T p.X157_splice | Splice Site (SNP) | VAF 46/94 reads (49%) | called by muse, mutect2, varscan2
- NHSL2 | c.145G>T p.G49W (on ENST00000510661; = p.G415W on NM_001013627.2) | Missense Mutation (SNP) | VAF 92/140 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NPAP1 | c.1082C>A p.S361Y | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NPIPB6 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 130/640 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); called by mutect2, varscan2
- NPPB | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NR1D2 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- NRAP | c.5140C>A p.P1714T (on ENST00000359988 / NM_001322945.2; = p.P1679T on NM_006175.4) | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- NUTM2B | c.1022C>A p.P341H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- NWD2 | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- NXNL2 | c.314del p.K105Rfs*12 | Frame Shift Del (DEL) | VAF 65/216 reads (30%) | called by mutect2, pindel, varscan2
- OPA1 | c.780G>T p.Q260H (on ENST00000361510 / NM_130837.3; = p.Q224H on NM_130832.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/377 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- OR10A5 | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 78/227 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10G2 | c.613T>C p.F205L | Missense Mutation (SNP) | VAF 64/354 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.236); called by muse, mutect2
- OR1G1 | c.343T>A p.L115M | Missense Mutation (SNP) | VAF 147/359 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- OR2M5 | c.218T>A p.L73H | Missense Mutation (SNP) | VAF 136/290 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OR51A2 | c.784G>T p.V262F | Missense Mutation (SNP) | VAF 130/271 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- OR51B2 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- OR52I1 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 47/371 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- OR6N2 | c.937A>G p.S313G | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, varscan2
- OSGEP | c.391G>T p.V131L | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- OVCH2 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 77/346 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- P2RX2 | c.1324A>G p.S442G (on ENST00000343948 / NM_170683.4; = p.S344G on NM_012226.5) | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAPPA | c.1618C>A p.H540N | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PCDHA9 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PDE8B | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 103/282 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PEAR1 | c.2842G>A p.G948S | Missense Mutation (SNP) | VAF 153/250 reads (61%) | SIFT tolerated (0.77); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.865A>C p.S289R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- PIDD1 | c.1566G>C p.Q522H | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIGR | c.2232A>T p.K744N | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PIK3AP1 | c.537G>C p.M179I | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PLD1 | c.2320A>T p.R774W | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- PLEKHA2 | c.201G>T p.V67= | Splice Region (SNP) | VAF 30/142 reads (21%) | called by muse, mutect2, varscan2
- PLEKHA4 | c.1569C>T p.S523= | Splice Region (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- PLEKHG3 | c.995A>G p.H332R (on ENST00000394691; = p.H388R on NM_001308147.2) | Missense Mutation (SNP) | VAF 106/492 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- PLXNA4 | c.4960C>A p.L1654I | Missense Mutation (SNP) | VAF 169/429 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- PNPLA1 | c.80A>T p.Y27F | Missense Mutation (SNP) | VAF 275/643 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRAMEF15 | c.697A>C p.M233L | Missense Mutation (SNP) | VAF 58/618 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- PRAMEF19 | c.347G>C p.W116S | Missense Mutation (SNP) | VAF 96/954 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- PRF1 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 166/467 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRG4 | c.261C>A p.D87E | Missense Mutation (SNP) | VAF 219/493 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKCB | c.206-1G>T p.X69_splice | Splice Site (SNP) | VAF 71/256 reads (28%) | called by muse, mutect2, varscan2
- PRKD3 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PRR23A | c.395G>T p.R132M | Missense Mutation (SNP) | VAF 120/443 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- PRR30 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PSD2 | c.360C>A p.D120E | Missense Mutation (SNP) | VAF 131/324 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTDSS1 | c.1290G>T p.W430C | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- PTEN | c.292_296del p.L98Tfs*7 | Frame Shift Del (DEL) | VAF 146/331 reads (44%) | called by mutect2, pindel, varscan2
- PWWP2A | c.956A>T p.Q319L | Missense Mutation (SNP) | VAF 62/372 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- R3HCC1L | c.1839T>A p.N613K (on ENST00000612478 / NM_001256619.2; = p.N599K on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- RANBP3L | c.972G>C p.L324F | Missense Mutation (SNP) | VAF 126/226 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASGRP3 | c.50G>T p.C17F | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM45 | c.610T>G p.Y204D | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- RBMXL2 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIMS2 | c.2167G>T p.V723F (on ENST00000666250 / NM_001348490.2; = p.V531F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RIMS2 | c.4019G>T p.G1340V | Missense Mutation (SNP) | VAF 65/384 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- RNF103 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 210/534 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- RNLS | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- ROBO3 | c.2691C>A p.S897R | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- RTL9 | c.3395A>C p.K1132T | Missense Mutation (SNP) | VAF 107/199 reads (54%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RUNX1T1 | c.56G>A p.C19Y | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- SCN11A | c.4513T>G p.F1505V | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SCN3A | c.5458C>A p.L1820M | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCOC | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 186/402 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SELENOO | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by mutect2, varscan2
- SEMG2 | c.1478G>C p.S493T | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- SERPINH1 | c.404A>T p.Y135F | Missense Mutation (SNP) | VAF 120/685 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SETX | c.6896T>G p.V2299G | Missense Mutation (SNP) | VAF 197/444 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SHROOM3 | c.546G>T p.Q182H | Missense Mutation (SNP) | VAF 151/478 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SIGLEC5 | c.908G>C p.R303P | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SLC10A2 | c.757T>A p.Y253N | Missense Mutation (SNP) | VAF 194/492 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC10A3 | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 80/125 reads (64%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- SLC22A31 | c.317A>T p.H106L | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- SLC22A9 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- SLC25A48 | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC35C2 | c.190A>T p.R64W | Missense Mutation (SNP) | VAF 124/373 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- SLC35D1 | c.644del p.G215Efs*13 | Frame Shift Del (DEL) | VAF 67/354 reads (19%) | called by mutect2, pindel, varscan2
- SLC5A1 | c.1217C>G p.T406S | Missense Mutation (SNP) | VAF 210/636 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2
- SLC5A1 | c.1286T>A p.F429Y | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC5A4 | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC6A17 | c.1188C>A p.H396Q | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SNRNP200 | c.2218del p.D740Tfs*4 | Frame Shift Del (DEL) | VAF 68/466 reads (15%) | called by mutect2, pindel, varscan2
- SPAG5 | c.2277G>C p.Q759H | Missense Mutation (SNP) | VAF 129/265 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- SPATA16 | c.799C>G p.R267G | Missense Mutation (SNP) | VAF 131/664 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATA5L1 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 108/372 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPEF2 | c.3288G>T p.W1096C | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SPHKAP | c.388G>T p.V130F | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SPNS2 | c.935A>G p.N312S | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SPOCK3 | c.1111G>T p.G371* | Nonsense Mutation (SNP) | VAF 45/99 reads (45%) | called by muse, mutect2, varscan2
- SPP2 | c.488A>G p.N163S | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SRMS | c.808C>G p.L270V | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- SSMEM1 | c.718A>G p.K240E | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.495); called by muse, varscan2
- STAC | c.245G>T p.S82I | Missense Mutation (SNP) | VAF 181/465 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- STARD9 | c.9397G>T p.E3133* | Nonsense Mutation (SNP) | VAF 137/312 reads (44%) | called by muse, mutect2, varscan2
- STAT2 | c.604A>T p.T202S | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- STX19 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SULT1C2 | c.794G>T p.W265L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SUZ12 | c.602G>T p.C201F | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SYCE2 | c.471C>A p.Y157* | Nonsense Mutation (SNP) | VAF 13/165 reads (8%) | called by muse, mutect2
- SYCP2 | c.3999T>G p.S1333R | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TADA2B | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 88/234 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TBX22 | c.1335T>A p.Y445* | Nonsense Mutation (SNP) | VAF 169/275 reads (61%) | called by muse, mutect2, varscan2
- TELO2 | c.972G>T p.M324I | Missense Mutation (SNP) | VAF 105/387 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX33 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- TEX51 | c.412T>A p.C138S (on ENST00000643416; = p.C114S on NM_001322244.2) | Missense Mutation (SNP) | VAF 52/326 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- TGFBR3L | c.578C>A p.P193Q | Missense Mutation (SNP) | VAF 134/352 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- THNSL2 | c.1362G>C p.M454I | Missense Mutation (SNP) | VAF 158/477 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- THSD1 | c.2358G>C p.R786S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- THSD7A | c.4524G>T p.M1508I | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM237 | c.79G>T p.D27Y (on ENST00000409883 / NM_001044385.3; = p.D19Y on NM_152388.4) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- TMLHE | c.83A>T p.Q28L | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNS3 | c.1728G>A p.M576I | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TOGARAM2 | c.2464G>C p.V822L | Missense Mutation (SNP) | VAF 134/411 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRAV9-1 | c.178G>T p.G60* | Nonsense Mutation (SNP) | VAF 84/462 reads (18%) | called by muse, mutect2, varscan2
- TRIM40 | c.50G>T p.C17F | Missense Mutation (SNP) | VAF 104/231 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRMT112 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 114/396 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- TRPV2 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- TSC22D2 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 99/324 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TSHZ2 | c.1806A>T p.K602N | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- TTLL6 | c.2499G>T p.Q833H (on ENST00000393382 / NM_001130918.3; = p.Q526H on NM_173623.3) | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TTN | c.78739G>T p.E26247* (on ENST00000591111; = p.E18823* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.56033G>T p.R18678M (on ENST00000591111; = p.R11254M on NM_003319.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.16475G>C p.G5492A (on ENST00000591111; = p.G4565A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/130 reads (17%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UEVLD | c.1276T>C p.F426L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ULK1 | c.1332T>G p.I444M | Missense Mutation (SNP) | VAF 86/196 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- UMOD | c.728T>A p.V243E | Missense Mutation (SNP) | VAF 117/460 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- UQCRC2 | c.932A>T p.Q311L | Missense Mutation (SNP) | VAF 153/514 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- VIPAS39 | c.451T>G p.Y151D | Missense Mutation (SNP) | VAF 271/563 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- WDR17 | c.632T>C p.V211A | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- WIF1 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- WWC3 | c.651_652insT p.G218Wfs*6 | Frame Shift Ins (INS) | VAF 74/159 reads (47%) | called by mutect2, pindel
- XDH | c.3739G>T p.D1247Y | Missense Mutation (SNP) | VAF 167/514 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ZBP1 | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 101/311 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ZDHHC14 | c.481A>T p.T161S | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- ZMYM4 | c.2552A>G p.Q851R | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF19 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 81/361 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ZNF280A | c.521A>G p.N174S | Missense Mutation (SNP) | VAF 148/328 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- ZNF280C | c.1090A>T p.T364S | Missense Mutation (SNP) | VAF 72/128 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ZNF335 | c.2729A>T p.Q910L | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ZNF41 | c.2257C>T p.Q753* | Nonsense Mutation (SNP) | VAF 48/162 reads (30%) | called by muse, mutect2, varscan2
- ZNF530 | c.589A>T p.S197C | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF582 | c.79C>A p.Q27K | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF670 | c.112A>G p.R38G | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ZNF676 | c.760G>A p.E254K (on ENST00000650058; = p.E222K on NM_001001411.3) | Missense Mutation (SNP) | VAF 94/380 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.954); called by muse, varscan2
- ZNF773 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 65/414 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF787 | c.1036G>T p.V346F | Missense Mutation (SNP) | VAF 148/436 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ZP2 | c.529G>T p.G177W | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- A4GNT | c.696G>A p.L232= | Silent (SNP) | VAF 117/370 reads (32%) | catalogued as rs889333352; called by muse, mutect2, varscan2
- ABL1 | c.1356A>T p.L452= | Silent (SNP) | VAF 73/181 reads (40%) | called by muse, mutect2, varscan2
- AC068580.4 | c.900C>T p.L300= | Silent (SNP) | VAF 85/477 reads (18%) | catalogued as COSV99362405; called by muse, mutect2, varscan2
- ACIN1 | c.4011G>T p.R1337= | Silent (SNP) | VAF 31/131 reads (24%) | called by muse, mutect2, varscan2
- ADAM21 | c.2106G>C p.G702= | Silent (SNP) | VAF 20/509 reads (4%) | called by muse, mutect2
- ADAMTS20 | c.1788G>T p.V596= | Silent (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- ADCY3 | c.1308G>T p.S436= | Silent (SNP) | VAF 142/464 reads (31%) | called by muse, mutect2, varscan2
- AFAP1L1 | c.426C>T p.I142= | Silent (SNP) | VAF 49/170 reads (29%) | called by muse, mutect2, varscan2
- AGBL5 | c.1722G>T p.P574= | Silent (SNP) | VAF 86/603 reads (14%) | called by muse, mutect2, varscan2
- AGXT2 | c.1071C>A p.P357= | Silent (SNP) | VAF 198/510 reads (39%) | called by muse, mutect2, varscan2
- AHNAK2 | c.10833G>T p.P3611= | Silent (SNP) | VAF 133/1031 reads (13%) | called by muse, mutect2, varscan2
- ANK3 | c.2574A>G p.E858= | Silent (SNP) | VAF 52/144 reads (36%) | called by muse, mutect2
- ANKRD55 | c.1830C>T p.T610= | Silent (SNP) | VAF 121/265 reads (46%) | called by muse, mutect2, varscan2
- ASPDH | c.712C>A p.R238= (on ENST00000389208 / NM_001114598.2; = p.R133= on NM_001024656.3) | Silent (SNP) | VAF 98/299 reads (33%) | called by muse, mutect2, varscan2
- ATP2A3 | c.1399C>A p.R467= | Silent (SNP) | VAF 104/277 reads (38%) | catalogued as COSV59234787; called by muse, mutect2, varscan2
- B3GNT3 | c.459G>T p.P153= | Silent (SNP) | VAF 20/318 reads (6%) | catalogued as rs369408980; called by muse, mutect2
- BMP3 | c.396G>T p.L132= | Silent (SNP) | VAF 27/159 reads (17%) | called by muse, mutect2, varscan2
- C19orf81 | c.285G>T p.L95= | Silent (SNP) | VAF 41/232 reads (18%) | called by muse, mutect2, varscan2
- CACNA1H | c.6447G>T p.R2149= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs1335259297; called by muse, mutect2, varscan2
- CADPS2 | c.2817G>C p.V939= | Silent (SNP) | VAF 70/178 reads (39%) | catalogued as COSV57348878; called by muse, mutect2, varscan2
- CAPN13 | c.72G>A p.L24= | Silent (SNP) | VAF 24/295 reads (8%) | catalogued as rs768376821; called by muse, mutect2
- CDRT15L2 | c.606G>A p.R202= | Silent (SNP) | VAF 18/290 reads (6%) | catalogued as rs1228946458; called by muse, mutect2
- CEBPE | c.246G>A p.P82= | Silent (SNP) | VAF 35/221 reads (16%) | catalogued as rs757072889; called by muse, mutect2, varscan2
- CEP170 | c.189C>T p.L63= | Silent (SNP) | VAF 64/156 reads (41%) | called by muse, mutect2, varscan2
- CEP350 | c.5505C>T p.S1835= | Silent (SNP) | VAF 106/241 reads (44%) | called by muse, mutect2, varscan2
- CMYA5 | c.5244A>G p.L1748= | Silent (SNP) | VAF 77/207 reads (37%) | called by muse, mutect2, varscan2
- CNMD | c.951C>T p.C317= | Silent (SNP) | VAF 53/127 reads (42%) | called by muse, mutect2, varscan2
- CNTN5 | c.2253C>A p.T751= | Silent (SNP) | VAF 30/177 reads (17%) | called by muse, mutect2, varscan2
- COL20A1 | c.1842G>A p.G614= | Silent (SNP) | VAF 27/129 reads (21%) | catalogued as rs374376106; called by muse, mutect2, varscan2
- COL20A1 | c.3585C>A p.A1195= | Silent (SNP) | VAF 79/410 reads (19%) | called by muse, mutect2, varscan2
- COL5A3 | c.2259T>A p.A753= | Silent (SNP) | VAF 41/156 reads (26%) | called by muse, mutect2, varscan2
- COL6A1 | c.2580C>T p.L860= | Silent (SNP) | VAF 96/446 reads (22%) | catalogued as COSV100719819; called by muse, mutect2, varscan2
- CREB3L3 | c.648C>T p.T216= | Silent (SNP) | VAF 48/606 reads (8%) | catalogued as rs747638223; called by muse, mutect2
- CSMD3 | c.4023C>A p.G1341= (on ENST00000297405 / NM_001363185.1; = p.G1237= on NM_052900.3) | Silent (SNP) | VAF 90/298 reads (30%) | called by muse, mutect2, varscan2
- CTCFL | c.378C>A p.P126= | Silent (SNP) | VAF 170/566 reads (30%) | catalogued as COSV99713329; called by mutect2, varscan2
- CTNNA2 | c.1359C>A p.T453= | Silent (SNP) | VAF 19/144 reads (13%) | called by muse, mutect2, varscan2
- DACT1 | c.2029C>A p.R677= | Silent (SNP) | VAF 135/360 reads (38%) | catalogued as rs868334123, COSV60019297; called by muse, mutect2, varscan2
- DLX2 | c.471C>T p.T157= | Silent (SNP) | VAF 58/471 reads (12%) | called by muse, mutect2, varscan2
- DMBX1 | c.924C>T p.N308= | Silent (SNP) | VAF 87/376 reads (23%) | called by muse, mutect2, varscan2
- EPG5 | c.39C>T p.A13= | Silent (SNP) | VAF 33/259 reads (13%) | called by muse, mutect2, varscan2
- EXOC1L | c.198A>G p.T66= | Silent (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- F11 | c.543C>A p.L181= | Silent (SNP) | VAF 54/141 reads (38%) | catalogued as COSV53007086; called by muse, mutect2, varscan2
- FBN3 | c.6081G>C p.S2027= | Silent (SNP) | VAF 27/382 reads (7%) | called by muse, mutect2
- FERD3L | c.216G>T p.G72= | Silent (SNP) | VAF 46/123 reads (37%) | called by muse, mutect2, varscan2
- FOXP2 | c.1167A>G p.Q389= | Silent (SNP) | VAF 116/351 reads (33%) | called by muse, mutect2, varscan2
- GAL3ST3 | c.780C>T p.D260= | Silent (SNP) | VAF 71/505 reads (14%) | called by muse, mutect2, varscan2
- GOLGA8T | c.753G>T p.R251= | Silent (SNP) | VAF 93/347 reads (27%) | called by muse, mutect2, varscan2
- GRAMD1B | c.111G>T p.T37= | Silent (SNP) | VAF 95/470 reads (20%) | catalogued as COSV73241009; called by muse, mutect2, varscan2
- GRID2IP | c.1938G>A p.G646= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs974110978; called by muse, mutect2, varscan2
- GRIK5 | c.1842G>T p.A614= | Silent (SNP) | VAF 50/266 reads (19%) | called by muse, mutect2, varscan2
- HAS3 | c.1512G>C p.L504= | Silent (SNP) | VAF 28/127 reads (22%) | called by muse, mutect2, varscan2
- HAUS5 | c.426G>A p.T142= | Silent (SNP) | VAF 92/306 reads (30%) | catalogued as rs373949368; called by muse, mutect2, varscan2
- HBG1 | c.207G>A p.L69= | Silent (SNP) | VAF 24/193 reads (12%) | called by muse, mutect2, varscan2
- HBG2 | c.207G>A p.L69= | Silent (SNP) | VAF 140/1762 reads (8%) | catalogued as rs1226055554; called by muse, mutect2
- HDLBP | c.855G>A p.K285= | Silent (SNP) | VAF 36/136 reads (26%) | called by muse, varscan2
- HFM1 | c.4044C>A p.S1348= | Silent (SNP) | VAF 31/226 reads (14%) | called by muse, mutect2, varscan2
- HOXC4 | c.210C>G p.T70= | Silent (SNP) | VAF 166/517 reads (32%) | called by muse, mutect2, varscan2
- HR | c.1698G>C p.L566= | Silent (SNP) | VAF 93/201 reads (46%) | called by muse, mutect2, varscan2
- IDE | c.108A>G p.K36= | Silent (SNP) | VAF 38/84 reads (45%) | called by muse, varscan2
- IDH3G | c.720A>C p.A240= | Silent (SNP) | VAF 49/89 reads (55%) | called by muse, mutect2, varscan2
- IFIH1 | c.1371C>T p.I457= | Silent (SNP) | VAF 24/182 reads (13%) | called by muse, mutect2, varscan2
- IGHD | c.1098C>A p.L366= | Silent (SNP) | VAF 319/586 reads (54%) | called by muse, mutect2, varscan2
- IGHG3 | c.1239C>T p.A413= | Silent (SNP) | VAF 327/686 reads (48%) | catalogued as rs1388924175; called by muse, mutect2, varscan2
- IGHV3-13 | c.267C>A p.S89= | Silent (SNP) | VAF 235/507 reads (46%) | called by muse, mutect2, varscan2
- IGKV2D-29 | c.213C>A p.L71= | Silent (SNP) | VAF 100/442 reads (23%) | catalogued as rs757009109, COSV101534368; called by muse, mutect2, varscan2
- IGKV3D-7 | c.252C>A p.A84= | Silent (SNP) | VAF 72/901 reads (8%) | called by muse, varscan2
- IGSF11 | c.267C>T p.H89= (on ENST00000393775 / NM_001015887.3; = p.H88= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/312 reads (25%) | catalogued as rs144392693; called by muse, mutect2, varscan2
- IGSF22 | c.1881C>A p.I627= | Silent (SNP) | VAF 46/267 reads (17%) | called by muse, mutect2, varscan2
- ITGA8 | c.822G>T p.G274= | Silent (SNP) | VAF 52/198 reads (26%) | catalogued as rs754561530, COSV100959447; called by muse, mutect2, varscan2
- KANSL3 | c.1581A>T p.S527= | Silent (SNP) | VAF 39/106 reads (37%) | called by muse, mutect2, varscan2
- KCNU1 | c.3294C>A p.S1098= | Silent (SNP) | VAF 40/88 reads (45%) | called by muse, mutect2, varscan2
- KDM4B | c.90A>G p.K30= | Silent (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- KIF26A | c.4524G>C p.S1508= | Silent (SNP) | VAF 36/221 reads (16%) | called by muse, mutect2, varscan2
- KRTAP13-1 | c.279G>A p.Q93= | Silent (SNP) | VAF 85/373 reads (23%) | called by muse, mutect2, varscan2
- KRTAP19-8 | c.165A>G p.G55= | Silent (SNP) | VAF 46/204 reads (23%) | catalogued as rs756282098, COSV101239202; called by muse, mutect2, varscan2
- LAMA3 | c.1299G>C p.A433= | Silent (SNP) | VAF 213/700 reads (30%) | called by muse, mutect2, varscan2
- LIG1 | c.1209G>T p.G403= | Silent (SNP) | VAF 82/501 reads (16%) | catalogued as rs1466321616; called by muse, mutect2, varscan2
- LILRA1 | c.213A>G p.T71= | Silent (SNP) | VAF 64/432 reads (15%) | called by muse, varscan2
- LILRA2 | c.1173G>C p.G391= | Silent (SNP) | VAF 108/677 reads (16%) | catalogued as COSV99253976; called by muse, mutect2, varscan2
- LMX1B | c.528C>G p.L176= | Silent (SNP) | VAF 67/283 reads (24%) | called by muse, mutect2, varscan2
- LYVE1 | c.12C>T p.C4= | Silent (SNP) | VAF 43/153 reads (28%) | called by muse, mutect2, varscan2
- MARK4 | c.1965G>T p.L655= (on ENST00000262891 / NM_001199867.2; = p.C682F on NM_031417.4) | Silent (SNP) | VAF 196/587 reads (33%) | called by muse, mutect2, varscan2
- MASP2 | c.1602A>C p.A534= | Silent (SNP) | VAF 46/154 reads (30%) | called by muse, mutect2, varscan2
- MNDA | c.1122G>A p.L374= | Silent (SNP) | VAF 18/210 reads (9%) | catalogued as rs560794903, COSV100933217, COSV63741706; called by muse, mutect2
- MPST | c.480C>T p.P160= (on ENST00000341116 / NM_001369904.2; = p.P180= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 80/674 reads (12%) | catalogued as rs767134012; called by muse, mutect2, varscan2
- MROH2B | c.3486G>A p.L1162= | Silent (SNP) | VAF 96/267 reads (36%) | called by muse, mutect2, varscan2
- MVB12A | c.592C>A p.R198= | Silent (SNP) | VAF 27/364 reads (7%) | catalogued as rs184098931; called by muse, mutect2
- MYH13 | c.5115G>C p.L1705= | Silent (SNP) | VAF 112/286 reads (39%) | called by muse, mutect2, varscan2
- NPHP4 | c.3732G>A p.Q1244= | Silent (SNP) | VAF 32/119 reads (27%) | called by muse, mutect2, varscan2
- NWD1 | c.363G>T p.L121= | Silent (SNP) | VAF 51/170 reads (30%) | called by muse, mutect2, varscan2
- OR14A2 | c.447T>C p.I149= | Silent (SNP) | VAF 68/141 reads (48%) | catalogued as rs186806563; called by muse, mutect2, varscan2
- OR5A1 | c.705G>A p.E235= | Silent (SNP) | VAF 38/154 reads (25%) | called by muse, mutect2, varscan2
- PCDHA4 | c.1770G>C p.V590= | Silent (SNP) | VAF 235/562 reads (42%) | called by muse, mutect2, varscan2
- PCDHGB6 | c.828G>A p.E276= | Silent (SNP) | VAF 32/195 reads (16%) | catalogued as rs377547144; called by muse, mutect2, varscan2
- PCK1 | c.231G>A p.L77= | Silent (SNP) | VAF 52/164 reads (32%) | called by muse, mutect2
- PKHD1 | c.10671A>T p.S3557= | Silent (SNP) | VAF 151/370 reads (41%) | called by muse, mutect2, varscan2
- PKHD1 | c.5376G>T p.L1792= | Silent (SNP) | VAF 157/444 reads (35%) | called by muse, mutect2, varscan2
- PLCZ1 | c.93A>G p.L31= | Silent (SNP) | VAF 96/246 reads (39%) | called by muse, mutect2, varscan2
- PLEKHG3 | c.1758C>T p.L586= (on ENST00000394691; = p.L642= on NM_001308147.2) | Silent (SNP) | VAF 234/674 reads (35%) | called by muse, mutect2, varscan2
- PLXNB2 | c.2436G>T p.T812= | Silent (SNP) | VAF 39/201 reads (19%) | catalogued as COSV63782671; called by muse, mutect2, varscan2
- PNOC | c.298C>A p.R100= | Silent (SNP) | VAF 44/117 reads (38%) | called by muse, mutect2, varscan2
- PPP1R2B | c.282C>A p.A94= | Silent (SNP) | VAF 92/545 reads (17%) | called by muse, mutect2, varscan2
- PRDM13 | c.1242G>T p.A414= | Silent (SNP) | VAF 106/252 reads (42%) | called by muse, mutect2, varscan2
- PREX1 | c.4206G>C p.T1402= | Silent (SNP) | VAF 45/206 reads (22%) | called by muse, mutect2, varscan2
- PRICKLE1 | c.2049C>T p.S683= | Silent (SNP) | VAF 100/751 reads (13%) | catalogued as rs1228564687, COSV58209084; called by muse, mutect2, varscan2
- PRIMPOL | c.660A>G p.S220= | Silent (SNP) | VAF 110/297 reads (37%) | catalogued as rs1216508698; called by muse, mutect2, varscan2
- PRR18 | c.813C>A p.R271= | Silent (SNP) | VAF 134/308 reads (44%) | called by muse, mutect2, varscan2
- PTPRD | c.4677G>A p.R1559= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as rs529492337, COSV61940563; called by muse, varscan2
- RALGAPA1 | c.2733G>T p.S911= | Silent (SNP) | VAF 60/202 reads (30%) | called by muse, mutect2, varscan2
- RIMBP2 | c.1824C>T p.P608= | Silent (SNP) | VAF 57/120 reads (48%) | catalogued as rs201176049; called by muse, mutect2, varscan2
- ROPN1L | c.273T>C p.Y91= | Silent (SNP) | VAF 53/112 reads (47%) | catalogued as rs768797028; called by muse, mutect2, varscan2
- RP1L1 | c.1329C>A p.A443= | Silent (SNP) | VAF 103/347 reads (30%) | called by muse, mutect2, varscan2
- RPGRIP1L | c.2286G>A p.G762= | Silent (SNP) | VAF 63/265 reads (24%) | catalogued as rs769599317; called by muse, mutect2, varscan2
- RYR1 | c.699C>A p.S233= | Silent (SNP) | VAF 222/658 reads (34%) | catalogued as COSV62096730; called by muse, mutect2, varscan2
- SCN3B | c.300G>T p.L100= | Silent (SNP) | VAF 108/610 reads (18%) | called by muse, mutect2, varscan2
- SDHAF4 | c.180A>T p.A60= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as rs766162289; called by muse, mutect2, varscan2
- SENP2 | c.855G>A p.L285= | Silent (SNP) | VAF 14/175 reads (8%) | called by muse, mutect2
- SHANK1 | c.516C>A p.A172= | Silent (SNP) | VAF 51/296 reads (17%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.2538C>T p.L846= | Silent (SNP) | VAF 49/418 reads (12%) | called by muse, mutect2, varscan2
- SLC5A6 | c.1044G>A p.L348= | Silent (SNP) | VAF 124/371 reads (33%) | catalogued as rs759599317; called by muse, mutect2, varscan2
- SLIT3 | c.1104C>A p.T368= | Silent (SNP) | VAF 42/203 reads (21%) | called by muse, mutect2, varscan2
- SNTB1 | c.738C>T p.L246= | Silent (SNP) | VAF 57/307 reads (19%) | catalogued as COSV101180108; called by muse, mutect2, varscan2
- STXBP2 | c.1092G>T p.L364= | Silent (SNP) | VAF 119/294 reads (40%) | called by muse, mutect2, varscan2
- SYNE2 | c.8739G>T p.L2913= | Silent (SNP) | VAF 95/367 reads (26%) | called by muse, mutect2, varscan2
- TACC3 | c.846C>T p.P282= | Silent (SNP) | VAF 71/326 reads (22%) | catalogued as rs201512395, COSV57605224; called by muse, mutect2, varscan2
- TBC1D3B | c.1578G>A p.Q526= | Silent (SNP) | VAF 79/824 reads (10%) | called by muse, mutect2, varscan2
- TBCD | c.2616C>T p.R872= | Silent (SNP) | VAF 92/161 reads (57%) | catalogued as rs752464161; called by muse, mutect2, varscan2
- THEM4 | c.33G>C p.T11= | Silent (SNP) | VAF 185/313 reads (59%) | catalogued as rs757144408; called by muse, mutect2, varscan2
- TMEFF1 | c.75G>T p.S25= | Silent (SNP) | VAF 113/288 reads (39%) | called by muse, mutect2, varscan2
- TMEM108 | c.63G>A p.L21= | Silent (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- TMEM98 | c.547C>T p.L183= | Silent (SNP) | VAF 138/340 reads (41%) | called by muse, mutect2, varscan2
- TOM1 | c.186G>A p.K62= | Silent (SNP) | VAF 35/231 reads (15%) | catalogued as rs61731672; called by muse, mutect2, varscan2
- TPH2 | c.1467G>T p.G489= | Silent (SNP) | VAF 117/496 reads (24%) | called by muse, mutect2, varscan2
- TRHR | c.447C>A p.V149= | Silent (SNP) | VAF 204/584 reads (35%) | catalogued as COSV61233231; called by muse, mutect2, varscan2
- TRPC4AP | c.1650A>G p.A550= | Silent (SNP) | VAF 95/302 reads (31%) | called by muse, mutect2, varscan2
- UNC5A | c.420C>A p.A140= | Silent (SNP) | VAF 118/402 reads (29%) | called by muse, mutect2, varscan2
- UNKL | c.1383A>T p.A461= | Silent (SNP) | VAF 100/428 reads (23%) | called by muse, mutect2, varscan2
- UTS2B | c.162A>T p.L54= | Silent (SNP) | VAF 28/161 reads (17%) | called by muse, mutect2, varscan2
- WEE2 | c.1074C>A p.V358= | Silent (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
- ZBTB46 | c.345G>T p.T115= | Silent (SNP) | VAF 88/410 reads (21%) | catalogued as COSV55509249; called by muse, varscan2
- ZNF485 | c.753C>T p.F251= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as rs538880745, COSV62424015; called by muse, mutect2, varscan2
- ZNF831 | c.2304C>T p.L768= | Silent (SNP) | VAF 71/205 reads (35%) | called by muse, mutect2, varscan2
- AC009237.3 | n.664G>C | RNA (SNP) | VAF 101/288 reads (35%) | called by muse, mutect2, varscan2
- AC044798.1 | n.253C>A | RNA (SNP) | VAF 45/123 reads (37%) | called by muse, mutect2, varscan2
- AC073648.1 | n.246C>A | RNA (SNP) | VAF 42/241 reads (17%) | catalogued as rs528813291; called by muse, mutect2, varscan2
- ADGB | c.4818+5450A>T | Intron (SNP) | VAF 182/415 reads (44%) | called by muse, mutect2, varscan2
- AL355922.1 | n.66C>G | RNA (SNP) | VAF 61/431 reads (14%) | called by muse, mutect2, varscan2
- AL355922.1 | n.67A>C | RNA (SNP) | VAF 60/426 reads (14%) | called by muse, mutect2, varscan2
- ANK1 | c.5395-1450C>T | Intron (SNP) | VAF 150/483 reads (31%) | catalogued as rs1206036817; called by muse, mutect2, varscan2
- ANKRD26P1 | n.309G>C | RNA (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- ARHGAP5 | c.-261G>T | 5'UTR (SNP) | VAF 76/321 reads (24%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+789G>C | Intron (SNP) | VAF 87/138 reads (63%) | called by muse, mutect2, varscan2
- ATP2B4 | c.3309+5777C>A | Intron (SNP) | VAF 57/141 reads (40%) | catalogued as COSV100397242; called by muse, mutect2, varscan2
- ATR | c.6898-44A>G | Intron (SNP) | VAF 30/131 reads (23%) | called by muse, mutect2, varscan2
- BAGE2 | n.150G>T | RNA (SNP) | VAF 46/783 reads (6%) | catalogued as rs1484471874; called by muse, mutect2
- C15orf54 | n.620C>T | RNA (SNP) | VAF 55/132 reads (42%) | called by muse, mutect2, varscan2
- CBLIF | c.1192+34A>G | Intron (SNP) | VAF 39/261 reads (15%) | called by muse, mutect2, varscan2
- CCDC74B | c.295+127G>A | Intron (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- CD82 | c.-102-2258G>T | Intron (SNP) | VAF 57/192 reads (30%) | called by muse, mutect2, varscan2
- CERS2 | c.-41-2720C>T | Intron (SNP) | VAF 42/255 reads (16%) | called by muse, mutect2, varscan2
- CILP2 | c.-64C>T | 5'UTR (SNP) | VAF 128/327 reads (39%) | catalogued as rs1473629762; called by muse, mutect2, varscan2
- COL24A1 | c.4782+967G>T | Intron (SNP) | VAF 36/236 reads (15%) | called by muse, mutect2, varscan2
- COL4A2 | c.1340-343C>A | Intron (SNP) | VAF 284/2082 reads (14%) | called by muse, varscan2
- CTSC | c.318+6825G>C | Intron (SNP) | VAF 115/404 reads (28%) | called by muse, mutect2, varscan2
- CYP11B1 | c.955-70C>A | Intron (SNP) | VAF 37/111 reads (33%) | catalogued as rs748749005; called by muse, mutect2, varscan2
- CYP21A1P | chr6:32009764 A>G | 3'Flank (SNP) | VAF 350/849 reads (41%) | called by muse, mutect2, varscan2
- DNAH14 | c.9205+9234G>A | Intron (SNP) | VAF 27/134 reads (20%) | catalogued as rs1413317259; called by muse, mutect2, varscan2
- DNM2 | c.1558-40C>T | Intron (SNP) | VAF 31/187 reads (17%) | catalogued as rs754309970; called by muse, mutect2, varscan2
- DST-AS1 | n.139+7478C>T | Intron (SNP) | VAF 78/202 reads (39%) | called by muse, mutect2, varscan2
- ERCC3 | c.2065-19G>T | Intron (SNP) | VAF 98/635 reads (15%) | called by muse, mutect2, varscan2
- ESD | c.768+1808G>T | Intron (SNP) | VAF 44/126 reads (35%) | called by muse, mutect2, varscan2
- FAM160B2 | c.1852-33C>T | Intron (SNP) | VAF 154/305 reads (50%) | catalogued as rs767650630; called by muse, mutect2, varscan2
- FAM90A20P | n.1354G>A | RNA (SNP) | VAF 72/1112 reads (6%) | catalogued as rs1172187911; called by muse, mutect2
- FIP1L1 | c.1175-2001G>T | Intron (SNP) | VAF 16/105 reads (15%) | catalogued as COSV104399971; called by muse, mutect2, varscan2
- GABRG2 | c.1249-1374C>A | Intron (SNP) | VAF 55/151 reads (36%) | called by muse, mutect2, varscan2
- GALNT14 | c.129+12734G>T | Intron (SNP) | VAF 53/378 reads (14%) | called by muse, mutect2, varscan2
- GCDH | c.334+36C>A | Intron (SNP) | VAF 88/227 reads (39%) | called by muse, mutect2, varscan2
- GRM1 | c.2661-7248C>A | Intron (SNP) | VAF 111/221 reads (50%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.1418C>A | RNA (SNP) | VAF 97/552 reads (18%) | called by muse, mutect2, varscan2
- GUCY1B2 | n.1091C>T | RNA (SNP) | VAF 70/170 reads (41%) | catalogued as rs765973471; called by muse, varscan2
- GUSBP10 | n.168del | RNA (DEL) | VAF 39/214 reads (18%) | called by pindel, varscan2
- GYS1 | c.-102C>G | 5'UTR (SNP) | VAF 46/265 reads (17%) | called by muse, mutect2, varscan2
- H2BP2 | chr1:143876185 C>A | 3'Flank (SNP) | VAF 262/1377 reads (19%) | called by muse, mutect2, varscan2
- HCRTR1 | chr1:31627365 C>A | 3'Flank (SNP) | VAF 28/179 reads (16%) | called by muse, mutect2, varscan2
- HLA-DQB2 | c.*820C>T | 3'UTR (SNP) | VAF 58/122 reads (48%) | catalogued as rs1168498269, COSV101370023; called by muse, mutect2, varscan2
- HTR3A | c.*512G>T | 3'UTR (SNP) | VAF 28/152 reads (18%) | called by mutect2, varscan2
- IL7 | c.*60T>C | 3'UTR (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- INTS8 | chr8:94823177 C>A | 5'Flank (SNP) | VAF 57/156 reads (37%) | called by muse, mutect2, varscan2
- KATNBL1 | c.883-569C>T | Intron (SNP) | VAF 27/49 reads (55%) | called by muse, mutect2
- KTN1 | c.4069+28A>T | Intron (SNP) | VAF 30/234 reads (13%) | called by muse, mutect2
- KTN1 | c.4069+30G>T | Intron (SNP) | VAF 29/227 reads (13%) | catalogued as COSV58540860; called by muse, mutect2
- LAIR2 | c.-53G>C | 5'UTR (SNP) | VAF 51/321 reads (16%) | catalogued as rs374118247; called by muse, mutect2, varscan2
- LY6H | c.68-112G>A | Intron (SNP) | VAF 35/104 reads (34%) | catalogued as rs1010617099; called by muse, mutect2, varscan2
- MARCHF1 | c.242+584C>A | Intron (SNP) | VAF 93/249 reads (37%) | called by muse, mutect2, varscan2
- MIGA2 | c.1011-9T>A | Intron (SNP) | VAF 131/269 reads (49%) | called by muse, mutect2, varscan2
- MIR493 | n.21C>G | RNA (SNP) | VAF 69/155 reads (45%) | called by muse, varscan2
- MOCS1 | c.*1093T>C | 3'UTR (SNP) | VAF 192/466 reads (41%) | called by muse, mutect2, varscan2
- MRPL3 | c.-99del | 5'UTR (DEL) | VAF 121/491 reads (25%) | called by mutect2, pindel, varscan2
- MS4A18 | chr11:60743915 C>A | 3'Flank (SNP) | VAF 141/382 reads (37%) | called by muse, mutect2, varscan2
- MYO3A | c.731+34G>T | Intron (SNP) | VAF 98/280 reads (35%) | called by muse, mutect2, varscan2
- NDRG4 | c.37+728T>C | Intron (SNP) | VAF 98/438 reads (22%) | catalogued as rs1215454600; called by muse, mutect2, varscan2
- OR10V2P | n.275C>A | RNA (SNP) | VAF 71/333 reads (21%) | called by muse, mutect2, varscan2
- OR2L1P | n.395C>A | RNA (SNP) | VAF 140/298 reads (47%) | called by muse, mutect2, varscan2
- OR2L1P | n.396C>A | RNA (SNP) | VAF 136/296 reads (46%) | catalogued as rs779726891; called by muse, mutect2, varscan2
- PACRG | c.292-64672G>C | Intron (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- PATZ1 | c.1335+1225G>A | Intron (SNP) | VAF 13/78 reads (17%) | called by muse, varscan2
- PAX1 | c.287-108C>G | Intron (SNP) | VAF 139/536 reads (26%) | catalogued as COSV101270266; called by muse, mutect2, varscan2
- PAX6 | c.766-27T>C | Intron (SNP) | VAF 96/387 reads (25%) | catalogued as rs370689142; called by muse, mutect2, varscan2
- PFKL | c.1191+11G>A | Intron (SNP) | VAF 32/145 reads (22%) | called by muse, mutect2, varscan2
- PHACTR1 | c.251-119604A>T | Intron (SNP) | VAF 184/401 reads (46%) | called by muse, mutect2, varscan2
- PNCK | c.*257A>G | 3'UTR (SNP) | VAF 102/179 reads (57%) | called by muse, mutect2, varscan2
- POLR1A | c.-2G>A | 5'UTR (SNP) | VAF 18/182 reads (10%) | catalogued as rs889546406; called by muse, mutect2
- PPP6R3 | c.*1999T>C | 3'UTR (SNP) | VAF 53/250 reads (21%) | called by muse, mutect2, varscan2
- PPY2P | n.186G>T | RNA (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- RASSF1 | c.369+442C>G | Intron (SNP) | VAF 22/125 reads (18%) | called by muse, mutect2, varscan2
- REG3G | c.*5G>C | 3'UTR (SNP) | VAF 20/100 reads (20%) | catalogued as COSV99709500; called by muse, mutect2, varscan2
- RGL3 | c.-11G>A | 5'UTR (SNP) | VAF 60/198 reads (30%) | catalogued as rs746751864; called by muse, mutect2
- RHCE | c.-9G>T | 5'UTR (SNP) | VAF 45/258 reads (17%) | called by muse, mutect2, varscan2
- RHD | c.-9G>T | 5'UTR (SNP) | VAF 49/717 reads (7%) | catalogued as COSV100155350; called by muse, mutect2
- RIC8B | c.1451+7861C>T | Intron (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- RPS13 | chr11:17077902 G>T | 5'Flank (SNP) | VAF 70/440 reads (16%) | called by muse, mutect2, varscan2
- RPS4XP21 | n.219C>A | RNA (SNP) | VAF 80/397 reads (20%) | called by muse, mutect2, varscan2
- SCN3A | c.4807+43C>G | Intron (SNP) | VAF 54/164 reads (33%) | called by muse, mutect2, varscan2
- SCN4B | c.*983C>A | 3'UTR (SNP) | VAF 19/112 reads (17%) | catalogued as rs773412025; called by muse, mutect2, varscan2
- SMKR1 | c.-45G>T | 5'UTR (SNP) | VAF 110/281 reads (39%) | called by muse, mutect2, varscan2
- SORBS2 | c.-45-3937G>T | Intron (SNP) | VAF 58/126 reads (46%) | called by muse, mutect2, varscan2
- SPATA9 | c.378+681A>G | Intron (SNP) | VAF 33/88 reads (38%) | catalogued as rs1317106817; called by muse, mutect2, varscan2
- SSPOP | n.8630G>T | RNA (SNP) | VAF 234/542 reads (43%) | called by muse, mutect2, varscan2
- TCF7 | c.636-1386C>A | Intron (SNP) | VAF 48/122 reads (39%) | called by muse, mutect2, varscan2
- TEKT4 | c.499-642C>A | Intron (SNP) | VAF 56/321 reads (17%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*1455A>T | 3'UTR (SNP) | VAF 55/232 reads (24%) | called by muse, mutect2, varscan2
- TMEM135 | c.*4255G>T | 3'UTR (SNP) | VAF 52/280 reads (19%) | called by muse, varscan2
- TTC27 | c.-19T>A | 5'UTR (SNP) | VAF 45/275 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10361-4195G>T | Intron (SNP) | VAF 51/162 reads (31%) | catalogued as COSV60120288; called by muse, mutect2, varscan2
- TTN | c.10361-4560C>A | Intron (SNP) | VAF 37/175 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.10360+3143C>A | Intron (SNP) | VAF 41/270 reads (15%) | called by muse, mutect2, varscan2
- VAPB | c.*3660A>T | 3'UTR (SNP) | VAF 63/216 reads (29%) | called by muse, mutect2, varscan2
- VIPR2 | c.357+6877G>A | Intron (SNP) | VAF 48/110 reads (44%) | called by muse, mutect2, varscan2
- VPS35 | c.-39G>A | 5'UTR (SNP) | VAF 87/217 reads (40%) | catalogued as rs768774857, COSV54478635; called by muse, mutect2, varscan2
- Y_RNA | chr1:31507837 C>A | 5'Flank (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2
